TARGET case TARGET-30-PAIPVH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/9cb18be3-120d-5303-b01f-6589e8114816

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 4.8 years (1,740 days); Year of diagnosis: 1998; Days to last follow up: 2,936 days (8.0 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAIPVH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
